Somatic mutation profile of tumor specimen TARGET-30-PAKHCF-01A (aliquot TARGET-30-PAKHCF-01A-01W) from TARGET case TARGET-30-PAKHCF, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 2.3 years (839 days).
Specimen TARGET-30-PAKHCF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 19c9f247-e93d-4613-ad72-fe2f232ce7c8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAKHCF-10A (Blood Derived Normal), aliquot TARGET-30-PAKHCF-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b2ba0360-3b67-4c6b-acfa-3551891cbffa

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 4, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C1orf174 | c.377T>C p.V126A | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1461928659, COSV64365904; called by muse, mutect2, varscan2
- RELB | c.1736C>G p.T579R | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.798); catalogued as COSV55510908; called by mutect2, varscan2
- ZNF676 | c.719A>T p.K240M (on ENST00000650058; = p.K208M on NM_001001411.3) | Missense Mutation (SNP) | VAF 75/265 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV68092924, COSV68093353; called by muse, varscan2
- KLHL13 | c.743G>T p.S248I | Missense Mutation (SNP) | VAF 32/468 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.842); called by muse, mutect2
- KIR2DS4 | c.471G>T p.G157= | Silent (SNP) | VAF 41/617 reads (7%) | called by muse, mutect2
- RBAK | c.1026G>A p.E342= | Silent (SNP) | VAF 83/411 reads (20%) | catalogued as COSV62331223, COSV62331630; called by muse, mutect2, varscan2
